Somatic mutation profile of tumor specimen CPT000819 (aliquot CPT000819-0010) from CPTAC case 100004028, project CPTAC-2 (Breast). Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 49.1 years (17,945 days).
Specimen CPT000819: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22818b68-ae74-4c63-8fe0-75a6f61b018b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000825 (Blood Derived Normal), aliquot CPT000825-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cf2b9af-2891-44bc-8686-9db10bdf72f7

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Intron 4, In Frame Del 2, Splice Site 2, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD36C | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.316); catalogued as rs761278529, COSV71726649; called by muse, mutect2, varscan2
- ASTN1 | c.3458C>T p.A1153V | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV62501502; called by muse, mutect2
- BORA | c.1655T>A p.M552K (on ENST00000613797; = p.M477K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV64695619; called by muse, mutect2, varscan2
- BUB3 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.052); catalogued as COSV64364072; called by muse, mutect2, varscan2
- CRABP1 | c.70+1G>C p.X24_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV55116154; called by muse, mutect2
- GEN1 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV58057820; called by muse, mutect2, varscan2
- GTF3C2 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 36/182 reads (20%) | catalogued as COSV99272228; called by muse, mutect2, varscan2
- HTR2C | c.1065G>T p.W355C | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52204543, COSV52219456; called by muse, mutect2, varscan2
- LIN9 | c.965C>T p.T322I (on ENST00000366808 / NM_001270410.2; = p.T267I on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV60246193; called by muse, mutect2
- MINAR1 | c.1784G>C p.S595T | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59585039; called by muse, mutect2, varscan2
- MUC16 | c.36663C>A p.S12221R | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs1410961430, COSV67463809, COSV67481019; called by muse, mutect2, varscan2
- NLRP4 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV56719293; called by muse, mutect2, varscan2
- OR5K4 | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61584066; called by muse, mutect2, varscan2
- OTOA | c.3431T>G p.L1144R (on ENST00000286149; = p.L1130R on NM_144672.4) | Missense Mutation (SNP) | VAF 132/376 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53760231; called by muse, mutect2, varscan2
- PDCD11 | c.1244A>G p.N415S | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV63934696; called by muse, mutect2, varscan2
- PRAMEF4 | c.305T>A p.L102H | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99339963; called by muse, mutect2, varscan2
- PRPF31 | c.785T>A p.F262Y | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as CD093538, COSV58086289; called by muse, mutect2, varscan2
- RTL3 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1410662969, COSV58183174; called by muse, mutect2, varscan2
- SLC12A1 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66797589; called by muse, mutect2, varscan2
- SRSF6 | c.141C>A p.D47E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54828416; called by muse, mutect2, varscan2
- SYNDIG1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 107/432 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs778443324, COSV100965292, COSV65237741; called by muse, mutect2, varscan2
- TMEM132C | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs922523578, COSV59416644, COSV59428604; called by muse, mutect2, varscan2
- TRPV5 | c.2077T>A p.S693T | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV54688170; called by muse, mutect2, varscan2
- ZNF536 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 154/262 reads (59%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); catalogued as COSV62829840; called by muse, mutect2, varscan2
- CDC7 | c.976_978del p.K326del | In Frame Del (DEL) | VAF 17/96 reads (18%) | called by pindel, varscan2
- KANSL1 | c.2504C>G p.P835R | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- KMT2B | c.6359A>G p.N2120S | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MTSS2 | c.865_888del p.G289_A296del | In Frame Del (DEL) | VAF 152/445 reads (34%) | called by mutect2, pindel, varscan2
- RYR2 | c.6770T>C p.L2257P | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SETDB1 | c.875+1G>C p.X292_splice | Splice Site (SNP) | VAF 19/378 reads (5%) | called by muse, mutect2
- WARS1 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CCDC141 | c.1332A>G p.E444= | Silent (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- OTOA | c.3430C>T p.L1144= (on ENST00000286149; = p.L1130= on NM_144672.4) | Silent (SNP) | VAF 131/376 reads (35%) | catalogued as COSV53760185; called by muse, mutect2, varscan2
- PCDHB12 | c.2055G>A p.S685= | Silent (SNP) | VAF 128/473 reads (27%) | catalogued as rs543195348, COSV53393662, COSV53399217; called by muse, mutect2, varscan2
- PRR32 | c.690G>T p.P230= | Silent (SNP) | VAF 55/272 reads (20%) | catalogued as COSV100947888, COSV64420750; called by muse, mutect2, varscan2
- RHNO1 | c.264C>T p.T88= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs1338547165, COSV63485561; called by muse, mutect2, varscan2
- SERPINB9 | c.663C>T p.Y221= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs139289070; called by muse, mutect2, varscan2
- SLC5A5 | c.300C>T p.L100= | Silent (SNP) | VAF 40/326 reads (12%) | called by muse, mutect2, varscan2
- WASHC5 | c.1428C>T p.F476= | Silent (SNP) | VAF 253/366 reads (69%) | catalogued as COSV59198912; called by mutect2, varscan2
- AC073107.1 | n.1417G>A | RNA (SNP) | VAF 4/11 reads (36%) | catalogued as rs533775660; called by mutect2, varscan2
- ANKRD7 | c.179+2965G>A | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as rs567855021, COSV54555911; called by muse, mutect2
- LINC01559 | n.400+1252C>G | Intron (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233419 C>G | 5'Flank (SNP) | VAF 65/338 reads (19%) | called by muse, mutect2, varscan2
- PPM1N | c.939+250G>T | Intron (SNP) | VAF 31/136 reads (23%) | catalogued as COSV55595235; called by muse, mutect2, varscan2
- WDR86 | c.163+397C>T | Intron (SNP) | VAF 36/214 reads (17%) | called by muse, mutect2
